Somatic mutation profile of tumor specimen TCGA-3A-A9IX-01A (aliquot TCGA-3A-A9IX-01A-11D-A40W-08) from TCGA case TCGA-3A-A9IX, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 40.3 years (14,729 days).
Specimen TCGA-3A-A9IX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42e24974-b2a0-4e48-a1c2-22153d9547a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3A-A9IX-10A (Blood Derived Normal), aliquot TCGA-3A-A9IX-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d5b9ca0-4830-4532-a8d0-f44b20cf8066

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GREB1 | c.4658G>A p.R1553H | Missense Mutation (SNP) | VAF 17/353 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267574622, COSV99303018; called by muse, mutect2
- HERPUD1 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 44/963 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.153); catalogued as rs373182203; called by muse, mutect2
- KCNH5 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 17/423 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs899330305, COSV59760144, COSV99063064; called by muse, mutect2
- KCNJ6 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 25/675 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs971698781, COSV99899916; called by muse, mutect2
- MBNL2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100600433; called by muse, mutect2
- RHBDF1 | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 30/642 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs759973395, COSV51954694; called by muse, mutect2
- SI | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs149498200; called by muse, mutect2
- SLC27A3 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 21/405 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as rs1396809758, COSV99669965; called by muse, mutect2
- WDR82 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 33/579 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV99626861; called by muse, mutect2
- WWC3 | c.2657A>G p.K886R | Missense Mutation (SNP) | VAF 48/463 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as COSV101081506; called by muse, mutect2, varscan2
- ZNF496 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 17/329 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99665725; called by muse, mutect2
- ALDH16A1 | c.577+1G>A p.X193_splice | Splice Site (SNP) | VAF 13/378 reads (3%) | called by muse, mutect2
- KCNA4 | c.564G>C p.E188D | Missense Mutation (SNP) | VAF 10/312 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2
- TROAP | c.337+168C>T | Intron (SNP) | VAF 12/282 reads (4%) | catalogued as COSV99226868; called by muse, mutect2
